Somatic mutation profile of tumor specimen TCGA-G9-7523-01A (aliquot TCGA-G9-7523-01A-11D-2260-08) from TCGA case TCGA-G9-7523, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 44.5 years (16,269 days).
Specimen TCGA-G9-7523-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e6b99b0-26d9-49a4-a654-13cd33c7ecbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-7523-10A (Blood Derived Normal), aliquot TCGA-G9-7523-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e985ba03-d2b6-4e16-b74c-cb8ca2f42fdd

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/138 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHCYL2 | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.162); catalogued as COSV61487248, COSV61487732; called by muse, mutect2, varscan2
- CDC6 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV52930547; called by muse, mutect2
- DAW1 | c.1157A>C p.H386P | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59365443; called by muse, mutect2
- FREM2 | c.2018G>C p.R673T | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV54838043; called by muse, mutect2
- IBTK | c.2091G>T p.R697S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60392948; called by muse, mutect2, varscan2
- MED24 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs145215690; called by muse, mutect2, varscan2
- MTF1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as COSV65989071; called by muse, mutect2
- RAPGEF4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV51389637; called by muse, mutect2, varscan2
- ADAMTS5 | c.1149C>T p.D383= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs1215587846, COSV53179228; called by muse, mutect2, varscan2
- C2orf76 | c.153C>T p.N51= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs973131908, COSV58346648; called by muse, mutect2, varscan2
- FURIN | c.1125C>T p.A375= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as rs201433527, COSV51576794; called by muse, mutect2, varscan2
- RAMP3 | c.378C>T p.P126= | Silent (SNP) | VAF 76/429 reads (18%) | catalogued as rs770078819, COSV54245141, COSV54245716; called by muse, mutect2, varscan2
- SAMD3 | c.1143T>C p.N381= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV62386309; called by muse, mutect2, varscan2
- SPINDOC | c.90G>A p.V30= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs1318105387, COSV53692578; called by muse, mutect2
